Somatic mutation profile of tumor specimen C3L-01201-54 (aliquot CPT0325890002) from CPTAC case C3L-01201, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 78.9 years (28,831 days).
Specimen C3L-01201-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5480f068-9d0f-4c05-abd6-93010f5ae962.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01201-50 (Buccal Cell Normal), aliquot CPT0325970003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8ecd78e-30aa-44f4-8c79-716d13d136b8

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 117/257 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAMKV | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377281206; called by muse, mutect2, varscan2
- KCNH1 | c.988T>A p.F330I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55069776; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2011C>T p.R671* (on ENST00000540229 / NM_001371097.1; = p.R610* on NM_001009562.4) | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | catalogued as rs1426459557, COSV67441338; called by muse, mutect2, varscan2
- BTN2A2 | c.414T>A p.D138E | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.074); called by muse, varscan2
- EEA1 | c.3977C>G p.A1326G | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- LIN28B | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.188); called by muse, mutect2
- ZNF732 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ENAH | c.803-599C>G | Intron (SNP) | VAF 113/232 reads (49%) | catalogued as COSV52867679; called by muse, mutect2, varscan2
